Gene-level copy-number profile of tumor specimen TCGA-85-8052-01A from TCGA case TCGA-85-8052, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.9 years (19,671 days).
Specimen TCGA-85-8052-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ba6e77de-ca9d-49d0-b72b-076484a16afb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8052-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a97b0f94-92af-45db-9c16-5bb90aadf03f

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 1: 34,748; copy number 2: 20,998; copy number 3: 4,062; copy number 4: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8052-01A-11D-2243-01): tumor purity 0.37, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,067 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,652,263–34,165,842, 81 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr1:48,497,263–50,023,954, 12 genes, copy number 3: AL356968.1, AGBL4, AL391844.1, BEND5, AL645507.1, AC099788.1, AGBL4-AS1, AGBL4-IT1, AL390023.1, ZNF859P, AL645730.1, MTND2P29.
- chr1:71,367,054–72,899,240, 12 genes, copy number 3–4 (within-gene range 2–4): AL358453.1, NEGR1, AL354949.1, AL359821.1, NEGR1-IT1, GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797.
- chr1:143,343,180–189,876,160, 1,367 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr1:246,178,778–248,919,946, 133 genes, copy number 3 (broad region; genes not listed).
- chr2:49,563,388–84,292,202, 558 genes, copy number 3 (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 3 (broad region; genes not listed).
- chr6:81,491,439–87,721,018, 97 genes, copy number 3 (broad region; genes not listed).
- chr15:27,621,534–28,322,179, 7 genes, copy number 3 (within-gene range 2–3): AC021979.1, AC021979.3, AC021979.2, OCA2, AC090696.1, RPL5P32, HERC2.

Autosomal genes at a single copy (total copy number 1): 32,327. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
